Somatic mutation profile of tumor specimen PCProject_0057_T1_WES (aliquot PCProject_0057_T1_WES_1) from CMI case PCProject_0057, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 51.6 years (18,850 days).
Specimen PCProject_0057_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b45455ce-799b-43f4-bd40-e2e0853b92f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0057_SALIVA (Saliva), aliquot PCProject_0057_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af3fcbee-d844-4f42-bb31-6c330509987d

The open-access MAF lists 28 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Intron 4, Silent 3, 3'UTR 3, Frame Shift Ins 3, RNA 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.260A>G p.Y87C | Missense Mutation (SNP) | VAF 12/126 reads (10%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen possibly damaging (0.539); catalogued as rs1057519971, COSV100753468, COSV61652670, COSV61653014; ClinVar: likely pathogenic; called by muse, mutect2
- MME | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated (0.8); PolyPhen benign (0.072); catalogued as rs200791566, COSV64710245; called by muse, mutect2, varscan2
- STAC | c.742G>T p.D248Y | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV56207388; called by muse, mutect2, varscan2
- ZNF479 | c.1046G>A p.R349K | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs1554400032; called by muse, mutect2, varscan2
- CAPN6 | c.1744G>C p.V582L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.649); called by muse, varscan2
- CCDC102B | c.32A>T p.E11V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); called by muse, mutect2
- COL9A3 | c.220G>A p.G74R | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DBN1 | c.758A>T p.E253V | Missense Mutation (SNP) | VAF 44/306 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- DOCK6 | c.1201T>G p.L401V | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- IGHMBP2 | c.1487dup p.C496Wfs*5 | Frame Shift Ins (INS) | VAF 32/204 reads (16%) | called by mutect2, varscan2
- IGHMBP2 | c.1491dup p.L498Afs*3 | Frame Shift Ins (INS) | VAF 29/243 reads (12%) | called by mutect2*, pindel, varscan2*
- KRR1 | c.1033A>G p.S345G | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OR5R1 | c.737T>A p.V246E | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, varscan2
- POT1 | c.398T>G p.V133G | Missense Mutation (SNP) | VAF 55/241 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SERP1 | c.89del p.N30Mfs*9 | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | called by mutect2, pindel
- SLX4 | c.4009dup p.R1337Kfs*55 | Frame Shift Ins (INS) | VAF 22/131 reads (17%) | called by mutect2, pindel, varscan2
- PCDHA2 | c.1612C>A p.R538= | Silent (SNP) | VAF 79/592 reads (13%) | catalogued as rs1554119985, COSV65369615; called by muse, mutect2, varscan2
- SLC6A11 | c.1890G>A p.T630= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs770168883, COSV99595220; called by muse, mutect2, varscan2
- YJU2 | c.93C>T p.Y31= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as rs774466060; called by muse, mutect2, varscan2
- CCDC188 | c.733-19T>C | Intron (SNP) | VAF 3/9 reads (33%) | catalogued as rs73150876; called by muse, mutect2
- CDKL1 | chr14:50395923 G>A | 5'Flank (SNP) | VAF 4/28 reads (14%) | catalogued as rs1288899809, COSV53578310; called by mutect2, varscan2
- OR2M1P | n.211G>A | RNA (SNP) | VAF 6/27 reads (22%) | catalogued as rs766518238; called by muse, mutect2, varscan2
- REV3L | c.9043-618T>A | Intron (SNP) | VAF 4/20 reads (20%) | catalogued as rs1356395055; called by muse, mutect2
- SNX6 | c.*11G>A | 3'UTR (SNP) | VAF 15/151 reads (10%) | catalogued as rs765117129; called by muse, mutect2, varscan2
- SRP19 | c.*1347G>A | 3'UTR (SNP) | VAF 31/193 reads (16%) | catalogued as rs1554093613; called by muse, mutect2, varscan2
- TNFRSF10B | c.*2072G>C | 3'UTR (SNP) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- TUBGCP2 | c.616+586A>G | Intron (SNP) | VAF 7/82 reads (9%) | called by muse, mutect2
- ZNF567 | c.136+22A>C | Intron (SNP) | VAF 11/117 reads (9%) | called by muse, mutect2, varscan2
